Somatic mutation profile of tumor specimen C3N-03666-01 (aliquot CPT0246720006) from CPTAC case C3N-03666, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 63.6 years (23,228 days).
Specimen C3N-03666-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8880674b-8d37-4fb0-af4d-fb44c231814e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03666-31 (Blood Derived Normal), aliquot CPT0246740002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f3cfd5f-ffc4-4940-8f6f-fe59bb18a3e8

The open-access MAF lists 117 somatic variants for this specimen: 81 protein-altering or splice-affecting, 24 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 24, 3'UTR 4, Splice Region 3, RNA 3, Intron 2, Nonsense Mutation 2, 5'UTR 2, Translation Start Site 1, Splice Site 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 74/454 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 161/799 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TRPS1 | c.2722C>T p.R908* (on ENST00000220888 / NM_001330599.2; = p.R921* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 132/931 reads (14%) | catalogued as rs751565386, CM154764, COSV55227212; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARAP3 | c.2114C>T p.P705L | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs756578535; called by muse, mutect2
- ARHGEF35 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 30/588 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs758435535; called by muse, mutect2
- BBOX1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1379464119, COSV54191958; called by muse, mutect2
- BOC | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs764634173, COSV56358734; called by muse, mutect2
- CARD11 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs1311406242, COSV62717219, COSV62720087; called by muse, mutect2
- CNTN6 | c.2493C>G p.N831K | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV63170693; called by muse, mutect2, varscan2
- CROCC | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.089); catalogued as rs1388968596; called by muse, mutect2
- CSH1 | c.278C>A p.T93K | Missense Mutation (SNP) | VAF 49/374 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100298304; called by muse, mutect2
- DNAH1 | c.11473C>T p.H3825Y | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758459337; called by muse, mutect2, varscan2
- FANCB | c.2014A>C p.M672L | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV100146553; called by muse, mutect2, varscan2
- FBN2 | c.8083G>A p.D2695N | Missense Mutation (SNP) | VAF 79/737 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs775607402, COSV52554909; called by muse, mutect2
- FNBP1 | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs367878072; called by muse, mutect2, varscan2
- FSCB | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 8/230 reads (3%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as COSV61216510; called by muse, mutect2
- GPM6A | c.322G>T p.G108W | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54534164, COSV99704812; called by muse, mutect2
- HSF5 | c.261C>A p.Y87* | Nonsense Mutation (SNP) | VAF 85/893 reads (10%) | catalogued as COSV60204808; called by muse, mutect2
- IRX1 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as rs753639527; called by muse, mutect2, varscan2
- KCTD5 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.604); catalogued as rs1302980196; called by muse, mutect2
- KIAA1614 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 13/215 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.286); catalogued as rs1325538323; called by muse, mutect2
- KIF19 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750093476; called by muse, mutect2, varscan2
- KIF26A | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 45/563 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs756312971; called by muse, mutect2
- LAMA2 | c.7781G>A p.R2594H | Missense Mutation (SNP) | VAF 41/554 reads (7%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.952); catalogued as rs368311592, COSV101370725; ClinVar: uncertain significance; called by muse, mutect2
- LMAN1L | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 34/371 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs543907196; called by muse, mutect2
- LYPD6 | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 53/498 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV61940055, COSV61941991; called by muse, mutect2, varscan2
- MUC16 | c.36913C>T p.R12305C | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.556); catalogued as rs367821186; called by muse, mutect2
- NOX3 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 35/385 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as rs76198873; called by muse, mutect2
- OBSL1 | c.3902G>A p.R1301H | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs746605175; called by muse, mutect2, varscan2
- PABPC5 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0.065); catalogued as COSV57040474; called by muse, mutect2, varscan2
- PCDHB5 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs782126497, COSV50658443; called by muse, mutect2, varscan2
- PRDX4 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs775157258; called by muse, mutect2, varscan2
- PRR16 | c.464G>A p.R155Q (on ENST00000407149 / NM_001300783.2; = p.R132Q on NM_016644.2) | Missense Mutation (SNP) | VAF 33/364 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.873); catalogued as rs760368454, COSV65394805; called by muse, mutect2
- RAD51C | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 71/454 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV61677100; called by muse, mutect2, varscan2
- RASGRP3 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 30/425 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251452351, COSV101274728; called by muse, mutect2
- RYR2 | c.7373C>T p.A2458V | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768478443, COSV63683125; called by muse, mutect2
- SLC1A6 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as rs146753676; called by muse, mutect2
- TNFAIP8L1 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 55/384 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs376296732; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3826G>A p.V1276I | Missense Mutation (SNP) | VAF 32/582 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs1360155092; called by muse, mutect2
- TPO | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.56); catalogued as rs772197481, COSV61097198; called by muse, mutect2, varscan2
- TTC24 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 44/622 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as rs574070584, COSV100964306, COSV63998350; called by muse, mutect2
- TTYH1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); catalogued as rs752243868; called by muse, mutect2
- VIM | c.1274-4T>G | Splice Region (SNP) | VAF 42/389 reads (11%) | catalogued as rs775056136; called by mutect2, varscan2
- ZFHX4 | c.4294C>T p.R1432C | Missense Mutation (SNP) | VAF 58/330 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761737101, COSV50854696; called by muse, mutect2, varscan2
- ZIC4 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs775064886; called by muse, mutect2
- ZNF665 | c.1613G>A p.C538Y (on ENST00000600412; = p.C603Y on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781368210; called by muse, mutect2, varscan2
- C8orf34 | c.878T>A p.I293N | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2
- CUBN | c.926G>T p.C309F | Missense Mutation (SNP) | VAF 60/779 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DCHS2 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 58/640 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.168); called by muse, mutect2
- DDX53 | c.1325A>C p.K442T | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.01); called by mutect2, varscan2
- DEFB128 | c.123A>T p.R41S | Missense Mutation (SNP) | VAF 76/796 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2
- DOCK10 | c.2825A>G p.D942G | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2
- ENAM | c.2800A>C p.N934H | Missense Mutation (SNP) | VAF 22/824 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAT4 | c.8678T>G p.V2893G | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FPGT-TNNI3K | c.1372T>C p.L458= | Splice Region (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2
- GOLGA8B | c.1559G>T p.S520I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.434); called by mutect2, varscan2
- GPR157 | c.699C>G p.I233M | Missense Mutation (SNP) | VAF 27/298 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- IPO8 | c.1899G>T p.E633D | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2
- KCNN2 | c.151G>C p.A51P (on ENST00000264773; = p.A263P on NM_021614.4) | Missense Mutation (SNP) | VAF 63/601 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC2 | c.1421C>G p.T474S | Missense Mutation (SNP) | VAF 31/432 reads (7%) | SIFT tolerated (0.06); called by muse, mutect2
- MYO16 | c.3883C>A p.Q1295K | Missense Mutation (SNP) | VAF 34/437 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- NCAM2 | c.1944A>T p.K648N | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2
- OXNAD1 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- PCDH8 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PCDHB4 | c.1757C>A p.T586N | Missense Mutation (SNP) | VAF 106/1263 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PLA2R1 | c.2762C>T p.T921I | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- RFLNA | c.515C>T p.P172L (on ENST00000546355 / NM_001365156.1; = p.P91L on NM_181709.4) | Missense Mutation (SNP) | VAF 123/756 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SARM1 | c.419_420insCT p.R141Cfs*28 | Frame Shift Ins (INS) | VAF 67/362 reads (19%) | called by mutect2, pindel, varscan2
- SLITRK3 | c.1624C>G p.L542V | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2
- SPATA31D1 | c.3845G>T p.C1282F | Missense Mutation (SNP) | VAF 35/291 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- STIL | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 28/355 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2
- SYT7 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- TADA1 | c.62A>T p.D21V | Missense Mutation (SNP) | VAF 92/419 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TBC1D8B | c.3220_3228delinsTG p.Q1074Cfs*12 | Frame Shift Del (DEL) | VAF 22/124 reads (18%) | called by pindel, varscan2*
- TPP2 | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2
- TRPM6 | c.337A>G p.R113G | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSGA10 | c.726T>A p.I242= | Splice Region (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- TTN | c.15952+1G>T p.X5318_splice (on ENST00000591111; = p.X4391_splice on NM_133378.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- VSIG8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/218 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- ZNF302 | c.579G>C p.K193N (on ENST00000627982; = p.K114N on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.044); called by muse, mutect2
- ZNF519 | c.1003C>A p.L335I | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- ADCY2 | c.2979C>T p.N993= | Silent (SNP) | VAF 60/323 reads (19%) | catalogued as rs958554402, COSV100601497, COSV100603231; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1011C>T p.R337= | Silent (SNP) | VAF 31/402 reads (8%) | catalogued as rs550598553; called by muse, mutect2
- CD22 | c.1572G>A p.S524= | Silent (SNP) | VAF 32/446 reads (7%) | catalogued as rs759785914, COSV50062887, COSV50070972; called by muse, mutect2
- CDH10 | c.339C>A p.A113= | Silent (SNP) | VAF 50/528 reads (9%) | catalogued as COSV100053091; called by muse, mutect2
- CDH5 | c.801G>A p.V267= | Silent (SNP) | VAF 36/152 reads (24%) | called by mutect2, varscan2
- COL15A1 | c.3271A>C p.R1091= | Silent (SNP) | VAF 31/402 reads (8%) | called by muse, mutect2
- CSMD1 | c.10497T>C p.A3499= (on ENST00000520002; = p.A3498= on NM_033225.6) | Silent (SNP) | VAF 31/257 reads (12%) | called by muse, mutect2, varscan2
- EDNRB | c.300C>T p.R100= (on ENST00000377211 / NM_001201397.1; = p.R10= on NM_000115.5) | Silent (SNP) | VAF 17/140 reads (12%) | catalogued as rs147694773; called by muse, mutect2, varscan2
- GSG1L2 | c.765C>T p.P255= | Silent (SNP) | VAF 35/312 reads (11%) | catalogued as rs1348182105; called by muse, mutect2, varscan2
- INTS1 | c.3315G>T p.S1105= | Silent (SNP) | VAF 50/283 reads (18%) | called by muse, mutect2, varscan2
- KCNA5 | c.1011C>T p.F337= | Silent (SNP) | VAF 36/416 reads (9%) | catalogued as rs977096843, COSV52904223, COSV52909110; called by muse, mutect2
- MIER2 | c.1485G>A p.E495= | Silent (SNP) | VAF 75/635 reads (12%) | called by muse, mutect2, varscan2
- NBPF3 | c.1728G>A p.S576= | Silent (SNP) | VAF 24/310 reads (8%) | catalogued as rs775331586, COSV59058154; called by muse, mutect2
- NLGN1 | c.1089T>C p.D363= | Silent (SNP) | VAF 79/242 reads (33%) | called by muse, mutect2, varscan2
- OPN5 | c.636G>A p.T212= | Silent (SNP) | VAF 42/531 reads (8%) | catalogued as COSV99790030; called by muse, mutect2
- SHISA9 | c.498C>T p.L166= | Silent (SNP) | VAF 26/276 reads (9%) | catalogued as rs1298699676, COSV69636279; called by muse, mutect2
- SI | c.1923C>T p.T641= | Silent (SNP) | VAF 21/512 reads (4%) | called by muse, mutect2
- SNX14 | c.975T>A p.P325= (on ENST00000314673 / NM_001350535.1; = p.P281= on NM_020468.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 33/358 reads (9%) | called by muse, mutect2
- SYNGR4 | c.369C>T p.F123= | Silent (SNP) | VAF 24/230 reads (10%) | catalogued as COSV61225315; called by muse, mutect2
- SYT11 | c.957G>A p.P319= | Silent (SNP) | VAF 91/338 reads (27%) | catalogued as rs370047410; called by muse, mutect2, varscan2
- TGIF2LX | c.567G>A p.P189= | Silent (SNP) | VAF 136/528 reads (26%) | catalogued as rs34232559, COSV99383208; called by muse, mutect2, varscan2
- TOR1AIP1 | c.942G>A p.Q314= | Silent (SNP) | VAF 20/403 reads (5%) | called by muse, mutect2
- UNKL | c.672T>C p.Y224= | Silent (SNP) | VAF 61/376 reads (16%) | called by muse, mutect2, varscan2
- WNK1 | c.4299C>T p.V1433= (on ENST00000315939 / NM_018979.4; = p.V1186= on NM_014823.3) | Silent (SNP) | VAF 46/446 reads (10%) | called by muse, mutect2, varscan2
- ABI3BP | c.1577-8510C>T | Intron (SNP) | VAF 34/681 reads (5%) | catalogued as rs1213387037; called by muse, mutect2
- AC079154.1 | n.1042G>A | RNA (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- AL353804.7 | chrX:73845776 ins G | 5'Flank (INS) | VAF 21/130 reads (16%) | called by mutect2, pindel, varscan2
- CATIP | c.*1G>A | 3'UTR (SNP) | VAF 29/284 reads (10%) | called by mutect2, varscan2
- EML3 | c.*27C>T | 3'UTR (SNP) | VAF 14/166 reads (8%) | catalogued as rs1047866726; called by muse, mutect2
- FOXG1 | c.-42G>A | 5'UTR (SNP) | VAF 18/188 reads (10%) | catalogued as rs1238378171; called by muse, mutect2
- HBB | c.*18C>T | 3'UTR (SNP) | VAF 48/583 reads (8%) | called by muse, mutect2
- NLGN4Y | c.*574C>A | 3'UTR (SNP) | VAF 17/346 reads (5%) | called by muse, mutect2
- PKD1P6 | n.3989C>T | RNA (SNP) | VAF 79/1060 reads (7%) | catalogued as rs1456814302; called by muse, mutect2
- PSMC2 | c.71-22C>T | Intron (SNP) | VAF 17/290 reads (6%) | catalogued as rs370547740; called by muse, mutect2
- RPS4Y2 | c.-3G>A | 5'UTR (SNP) | VAF 27/240 reads (11%) | called by muse, mutect2, varscan2
- SNX29P2 | n.764C>T | RNA (SNP) | VAF 46/690 reads (7%) | catalogued as rs373483734; called by muse, mutect2
